Gene-level copy-number profile of tumor specimen TCGA-GS-A9U4-01A from TCGA case TCGA-GS-A9U4, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 27.6 years (10,075 days).
Specimen TCGA-GS-A9U4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.66177c56-58d2-48cb-a7aa-c3f5ee437e39.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GS-A9U4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 359 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ad025c7-5e67-44c2-8a40-1498dcd9fa76

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 745; copy number 1: 4,576; copy number 2: 45,446; copy number 3: 7,004; copy number 4: 2,425; copy number 5: 58; copy number 6: 2; copy number 7: 1; copy number 8: 1; copy number 9: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GS-A9U4-01A-11D-A38W-01): tumor purity 0.19, ploidy 2.19, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 225 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–147,003,618, 111 genes (broad region; genes not listed).
- chr3:128,181,402–128,194,452, 1 gene: AL449214.1.
- chr6:24,804,282–25,057,073, 8 genes (within-gene range 0–2): RIPOR2, MTCO2P33, PPIAP29, AL160400.1, ASS1P1, RN7SL334P, AL133268.3, AL133268.2.
- chr7:84,847,877–84,848,253, 1 gene: AC093716.1.
- chr9:20,532,552–20,533,339, 1 gene: AL163193.1.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr11:58,387,583–58,388,486, 1 gene: OR5B15P.
- chr13:70,564,267–70,564,437, 1 gene: AL445264.1.
- chr14:22,123,318–22,613,215, 98 genes (within-gene range 0–2) (broad region; genes not listed).
- chr17:41,271,311–41,276,697, 2 genes (within-gene range 0–2): KRTAP9-11P, KRTAP9-7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 68 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:58,633,946–58,666,834, 1 gene, copy number 7 (within-gene range 2–7): FAM3D.
- chr5:151,380,341–151,382,381, 1 gene, copy number 8: AC034205.3.
- chr8:150,584–2,926,689, 57 genes, copy number 5: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1.
- chr8:3,373,353–3,375,226, 1 gene, copy number 5: AC026991.1.
- chr11:102,691,487–102,727,050, 2 genes, copy number 6 (within-gene range 3–6): MMP27, MMP8.
- chr17:46,029,916–46,225,389, 1 gene, copy number 9 (within-gene range 2–9): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 9: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 4,576. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
